Somatic mutation profile of tumor specimen MP2PRT-PAVEDY-TMP1-A (aliquot MP2PRT-PAVEDY-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVEDY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,793 days).
Specimen MP2PRT-PAVEDY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2086c35-711e-4afe-a842-d27e0a0564da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEDY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEDY-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/055ca9ba-dfd8-4d8e-a094-28679125b55c

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Frame Shift Ins 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCK1 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 143/465 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs748682003, COSV60130976, COSV60131680; called by muse, mutect2, varscan2
- SETDB1 | c.3802G>A p.E1268K (on ENST00000271640 / NM_001366417.1; = p.E1267K on NM_012432.4) | Missense Mutation (SNP) | VAF 93/349 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54987527; called by muse, mutect2, varscan2
- VTI1A | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs755885630, COSV67583967; called by muse, mutect2, varscan2
- ELL3 | c.164dup p.G56Rfs*29 | Frame Shift Ins (INS) | VAF 99/385 reads (26%) | called by mutect2, pindel, varscan2
- NOP53 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 32/355 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH2B3 | c.871dup p.D291Gfs*11 | Frame Shift Ins (INS) | VAF 84/252 reads (33%) | called by mutect2, pindel, varscan2
- SPI1 | c.296_297dup p.M100Pfs*87 | Frame Shift Ins (INS) | VAF 107/598 reads (18%) | called by pindel, varscan2
- TRPC7 | c.2186T>C p.L729P | Missense Mutation (SNP) | VAF 92/368 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- UBQLN4 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 138/472 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ATP2B3 | c.159C>T p.Y53= | Silent (SNP) | VAF 24/799 reads (3%) | catalogued as rs189900886; called by muse, mutect2
- KCNK10 | c.123G>A p.P41= | Silent (SNP) | VAF 74/1204 reads (6%) | catalogued as rs867074103, COSV56640940, COSV56642195; called by muse, mutect2
- KDM4F | c.132C>T p.G44= | Silent (SNP) | VAF 18/486 reads (4%) | called by muse, mutect2
- RICTOR | c.2397C>T p.D799= | Silent (SNP) | VAF 90/330 reads (27%) | called by muse, varscan2
- GRHL3 | c.1694+4333C>T | Intron (SNP) | VAF 44/255 reads (17%) | catalogued as rs369481155; called by muse, mutect2
